Surgical pathology report (de-identified scan), TCGA case TCGA-T3-A92N, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Molecular Response, specimen TCGA-T3-A92N-01A (Primary Tumor).

[page 1 of 5]
Site ID:

Subject Number:

Please complete ALL information with black ball point pen. Ensure information is legible.
Retain original and email/fax copy to

Sample Collection Date:	D D - M M - Y Y Y Y	Procured by: _____
Time of Tumor Sample Excision (24 hour clock):	H H : M M	Time Zone: _____
TUMOR-FROZEN & FRESH SAMPLES FROZEN SAMPLES BATCH SHIPPED (dry ice); FRESH TUMOR SAMPLE, IF COLLECTED, SHIPPED ON DAY OF COLLECTION		
Collect resected tumor in accordance with standard procedures. Weigh the sample and section off ~100mg. Frozen Tumor (Required) Place this sample in the cryovial labeled Frozen Tumor sample and record the weight. Place the cryovial in a can and then into the vapor phase dewar. Record the time placed in dewar.		
Weight of Tissue: 130 mg (tissue weight must be ≥ 100mg)	Time placed in dewar: (24 hour clock)	H H : M M
Fresh Tumor (Optional) ☐ N/A Locate the "Fresh Tumor" label in the kit and affix to the 15ml _____ tube (sent separately). Place any remaining tumor tissue into the 15ml conical tube containing _____		
Weight of Tissue: 370 mg (no min. weight specified)	Time placed in (24 hour clock)	Lot Number: _____ H H : M M
WHOLE BLOOD SAMPLE (Required) - BATCHED SHIPPED FROZEN		
Sample Collection Date:	D D - M M - Y Y Y Y	Procured by: _____
Time of Blood Sample Collection (24 hour clock):	H H : M M	Time Zone: _____
1-10ml EDTA tube. Fill tube completely and mix by gentle inversion at least 8-10 times. Freeze sample on dry ice or place in vapor phase dewar.		
Time placed in dry ice/dewar: (24 hour clock) H H : M M		
BASIC PATHOLOGICAL INFORMATION		
Clinical Diagnosis: (Ex. Lung Cancer)	HEAD/NECK CANCER	Source of Specimen: (Ex. Right Lung) FLOOR of MOUTH

Confidential
Valid from

ICD O-3

Carcinoma, squamous cell NOS 867d3
Site Floor of mouth NOS C04.9
9/23/26/14

[page 2 of 5]
Surg Path Final Report

* Final Report *

Result Type: Surg Path Final Report
Result Date:
Result Status:
Result Title:
Verified By:
Encounter info:

* Final Report *

Gross Description (Verified)

"FSA-B." All frozen section tissue is submitted in cassette "FSA-B," one (1) black, one (1) blue.

"FSC-D." All frozen section tissue is submitted in cassette "FSC-D," one (1) black, one (1) blue.

"FSE-F." All frozen section tissue is submitted in cassette "FSE-F," two (2) black, one (1) blue.

"Specimen G." The specimen consists of a 4.5 x 4.0 x 2.0 cm pink-tan, focally charred tissue fragment. One (1) surface has pink-tan, glistening mucosa. There is no oriented, and the margin will be inked black. There is a 2.0 x 1.0 cm ulcerated, red-brown area within the central mucosa. Previous sectioning reveals a 2.7 x 2.5 cm white-tan, firm mass. This mass grossly appears to abut the inked resection margin. "G1-G5," fragments, representative.

"H, Left submental node." The specimen consists of a 1.5 cm pink-tan lymph node. The specimen is bisected. "H," 2p, all.

"I, Left level 1B." The specimen consists of a 5.5 x 5.0 x 3.5 cm brown-black, hair-bearing skin fragment with underlying subcutaneous tissue. The specimen will be inked black. There is no orientation. On sectioning, there is an underlying 3.5 x 2.5 x 4.0 cm white-tan mass. This abuts the inked margin. Free in the container is a 4.0 x 4.0 x 3.0 cm pale tan, lobulated submandibular gland. This will be inked blue. On sectioning, there is a 1.2 cm white-tan, firm area located on the periphery of the specimen. The remaining cut surface has a yellow-tan, unremarkable appearance. "I1-I4," skin fragment; "I5-I7," submandibular gland, representative.

"J, Left level 1B and 1A." The specimen consists of a 7.5 x 5.5 x 2.5 cm yellow-tan to red-brown, firm mass. On examination, there is a 5.0 cm irregular, gray-white, firm mass with three (3) attached lymph nodes. These lymph nodes range in size from 0.7 to 1.2 cm. "J1," possible lymph nodes; "J2-J4," mass, representative.

"K, Left level 2 and 3." The specimen consists of a 6.0 x 5.0 x 2.0 cm aggregate of yellow-tan, fatty tissue. On examination, twelve (12) possible lymph nodes are identified. These range in size from 0.2 to 0.6 cm. "K1-K3," fragments, representative.

"L, Left level 2B." The specimen consists of a 3.5 x 3.5 x 1.0 cm yellow-tan, fatty fragment. On examination, two (2) possible lymph nodes are identified. These measure 0.3 and 0.4 cm. "L," 2p, representative.

"M, Left parafacial node." The specimen consists of a 1.5 cm gray-tan lymph node. The specimen is bisected. "M," 2p, all.

"N, Right level 1B." The specimen consists of a 4.2 x 3.5 x 2.2 cm pink-tan, lobulated submandibular gland. The specimen is inked black. On sectioning, the specimen grossly appears to be unremarkable. "N1-N4," fragments, representative.

"O, Right level 1A." The specimen consists of a 3.0 x 2.0 x 1.0 cm aggregate of yellow-tan, fatty tissue. On examination, four (4) possible

[page 3 of 5]
Surg Path Final Report

* Final Report *

lymph nodes are identified. These range in size from 0.5 to 0.7 cm. "Q," 4p, representative.

"P, Right level 2 and 3." The specimen consists of a 5.0 x 4.2 x 2.0 cm aggregate of yellow-tan, fatty tissue. On examination, seven (7) possible lymph nodes are identified. These range in size from 0.7 to 1.5 cm. "P1-P2," fragments, representative.

"Q, Right level 2B." The specimen consists of a 1.5 x 0.7 x 0.2 cm aggregate of yellow-tan, fatty tissue. Definite lymphoid tissue is not identified. "Q," fragments, all.

Frozen Section Diagnosis (Verified)

No time in or time out is given.

History: FOM tumor.

FSA Anterior FOM margin (blue) biopsy:

No tumor.

FSB Deep midline anterior FOM margin (black) biopsy:

No tumor.

FSC Deep right FOM margin (blue) biopsy:

No tumor.

FSD Mucosa right ventral tongue margin (black) biopsy:

No tumor.

FSE Mucosa midline ventral tongue margin (blue) biopsy:

No tumor.

FSF Deep midline anterior FOM margin (black) biopsy:

No tumor.

Clinical Information (Verified)

Floor of mouth cancer.

Final Diagnosis (Verified)

Left anterior floor of mouth margin, biopsy with frozen section:

No tumor seen.

Deep mid line anterior floor of mouth margin, biopsy with frozen section:

No tumor seen.

Deep right floor of mouth margin, biopsy with frozen section:

No tumor seen.

[page 4 of 5]
Surg Path Final Report

* Final Report *

Mucosa right ventral tongue margin, biopsy with frozen section:
No tumor seen.

Mucosa mid line ventral tongue margin, biopsy with frozen section:
No tumor seen.

Deep mid line anterior floor of mouth margin, biopsy with frozen section:
No tumor seen.

Floor of mouth tumor, resection:
Invasive poorly differentiated squamous cell carcinoma.
Maximal tumor diameter is 2.7 cm.
Perineural tumor is present.

Left submental lymph node, excision:
One (1) benign lymph node with no evidence of metastatic neoplasm.

0/1

Left level 1 neck contents, excision:
Soft tissue deposit of metastatic moderate to poorly differentiated squamous cell carcinoma with no evidence of residual lymph node.
* Maximal tumor diameter is 4 cm and tumor is present at the inked excision margin.
Tumor focally invades adjacent salivary tissue.

Left level 1B and 1A neck contents, excision:
Metastatic moderate to poorly differentiated squamous cell carcinoma involving one (1) ¹/₄ of four (4) identified lymph nodes with majority of tumor present outside of lymph node in soft tissue with maximal tumor diameter measuring 5 cm.

Left level 2 and 3 neck contents, excision:
Twelve (12) benign lymph nodes with no evidence of metastatic neoplasm.

0/12

Left level 2B neck contents, excision:
Two (2) benign lymph nodes with no evidence of metastatic neoplasm.

0/2

Left parafacial lymph node, excision:

[page 5 of 5]
Surg Path Final Report

* Final Report *

One (1) benign lymph node with no evidence of metastatic neoplasm.

0/1

Right level 1B neck contents, excision:

Benign salivary tissue.

No metastatic neoplasm identified.

C

Right level 1A neck contents, excision:

Metastatic poorly differentiated squamous cell carcinoma in two (2) of four (4) submitted lymph nodes, largest focus of tumor measures 5 mm and there is no evidence of extranodular tumor extension.

2/4

Right level 2 and 3 neck contents, excision:

Metastatic poorly differentiated squamous cell carcinoma involving three (3) of seven (7) submitted lymph nodes, largest focus measures 6 mm, with one (1) node demonstrating an area of extranodal tumor extension.

3/7

Right neck contents, level 2B, excision:

One (1) benign lymph node with no evidence of metastatic neoplasm.

AJCC pathologic stage T2.N2c.

[Redacted]

Page 4 of 4
(End of Report)

Source: NCI Genomic Data Commons file dbb73256-47ed-4dfe-a711-c6fb50299165 (TCGA-T3-A92N.92381BD3-D663-4BED-8530-DB6226CC179E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).